Somatic mutation profile of tumor specimen TCGA-CS-5394-01A (aliquot TCGA-CS-5394-01A-01D-1468-08) from TCGA case TCGA-CS-5394, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 40.8 years (14,920 days).
Specimen TCGA-CS-5394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0c59e5c-c275-42ca-80e1-18f7b252bb42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-5394-10A (Blood Derived Normal), aliquot TCGA-CS-5394-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1d996b5-c167-453e-b32c-5d3bcde868a4

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1351_1356del p.E451_Y452del (on ENST00000521381 / NM_181523.3; = p.E181_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 21/45 reads (47%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACTA2 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs772919504, COSV56518199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGPTL2 | c.1235A>G p.N412S | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52233324; called by muse, mutect2, varscan2
- APPBP2 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV50029740; called by muse, mutect2
- FSTL5 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs1429314225, COSV60222425, COSV60231556; called by muse, mutect2, varscan2
- FUBP1 | c.1610G>A p.W537* | Nonsense Mutation (SNP) | VAF 24/30 reads (80%) | catalogued as COSV53938439, COSV53938581; called by muse, mutect2, varscan2
- HELZ2 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as rs779018772, COSV64410509; called by muse, mutect2, varscan2
- HKDC1 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs764742218, COSV63579516; called by muse, mutect2, varscan2
- JKAMP | c.854T>A p.V285E (on ENST00000554271 / NM_001284201.1; = p.V271E on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV54201571; called by muse, mutect2, varscan2
- LSM14B | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV53383821; called by muse, mutect2, varscan2
- MEN1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as COSV53648659; called by muse, mutect2, varscan2
- MFAP1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs202057440, COSV51041486; called by muse, mutect2, varscan2
- MTUS2 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV70918541, COSV70922998; called by muse, mutect2, varscan2
- PAX4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs747805740, COSV58389181; called by muse, mutect2, varscan2
- RYR3 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV101213034, COSV66777888, COSV66809105; called by muse, mutect2, varscan2
- TAF1B | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55158367, COSV55160062; called by muse, mutect2, varscan2
- TAGLN2 | c.151A>G p.N51D | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs1402269524, COSV57423745; called by muse, mutect2, varscan2
- XAB2 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64322867; called by muse, mutect2
- CIC | c.4359dup p.E1454Rfs*3 | Frame Shift Ins (INS) | VAF 20/39 reads (51%) | called by mutect2, pindel, varscan2
- HDAC2 | c.394dup p.M132Nfs*4 | Frame Shift Ins (INS) | VAF 44/111 reads (40%) | called by mutect2, pindel, varscan2
- PCDH10 | c.257_260del p.K86Rfs*41 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- HSPA5 | c.987G>A p.E329= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV52338356, COSV99413626; called by muse, mutect2
- JKAMP | c.855G>A p.V285= (on ENST00000554271 / NM_001284201.1; = p.V271= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs1450104910, COSV54201592; called by muse, mutect2, varscan2
- MED14 | c.714A>G p.G238= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV61358631; called by muse, mutect2, varscan2
- PBRM1 | c.3120C>G p.V1040= (on ENST00000296302 / NM_001366071.2; = p.V1015= on NM_018313.5) | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs1037450091, COSV56305428; called by muse, mutect2, varscan2
- SULF2 | c.1362G>T p.A454= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV63420196; called by muse, mutect2, varscan2
- ABCA10 | c.-2T>A | 5'UTR (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99287645; called by muse, mutect2, varscan2
